Surgical pathology report (de-identified scan), TCGA case TCGA-27-1831, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1831-01A (Primary Tumor).

Ref. Number

TCGA-27-1831

Gender

Birth date

Tumor site

Right temporal parietal

Histological diagnosis

Glioblastoma multiforme

Note: for

only

Source: NCI Genomic Data Commons file 1fd0aff5-b9e2-4274-a36c-1ed322fffbdb (TCGA-27-1831.7DAE7D19-47B9-41E7-9DDE-293ED9A2BC26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).